Somatic mutation profile of tumor specimen TARGET-10-PARCVT-09A (aliquot TARGET-10-PARCVT-09A-01D) from TARGET case TARGET-10-PARCVT, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.8 years (5,419 days).
Specimen TARGET-10-PARCVT-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 800afc63-e1a5-4e9f-9c12-69bd19be9d8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARCVT-10A (Blood Derived Normal), aliquot TARGET-10-PARCVT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d81fddc-f544-405e-975f-46d21d59e865

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 26/36 reads (72%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- DNAH2 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 41/44 reads (93%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs199949904; called by muse, mutect2, varscan2
- GRIA2 | c.1349C>G p.A450G | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV52382371; called by muse, mutect2, varscan2
- MTOR | c.5920T>C p.Y1974H | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63869915; called by muse, mutect2, varscan2
- NUP88 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs201799531; called by muse, mutect2, varscan2
- SUPT6H | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 57/64 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58930768; called by muse, mutect2, varscan2
- DNAH11 | c.2864T>C p.I955T | Missense Mutation (SNP) | VAF 81/87 reads (93%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PPFIA2 | c.2389C>T p.R797* | Nonsense Mutation (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
- SLITRK2 | c.390C>A p.F130L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USH2A | c.8253C>T p.N2751= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs368877266; ClinVar: likely benign; called by muse, mutect2, varscan2
- XIRP2 | c.*1345T>A | 3'UTR (SNP) | VAF 54/61 reads (89%) | called by muse, mutect2
